Gene-level copy-number profile of tumor specimen ALCH-B396-TTP1-A from ALCHEMIST case ALCH-B396, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.7 years (20,361 days).
Specimen ALCH-B396-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 50585fd4-655d-451c-90be-d2884562aec0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B396-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/80295f3c-7659-4f02-82d8-61609b8a2e91

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 4,068; copy number 2: 47,429; copy number 3: 6,866; copy number 4: 26.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,792,796–15,793,285, 1 gene: RPL12P14.
- chr1:47,225,797–47,230,750, 1 gene (within-gene range 0–1): AL135960.1.
- chr12:132,351,855–132,361,198, 2 genes: AC148477.8, AC148477.6.
- chr13:31,311,289–31,312,921, 1 gene (within-gene range 0–2): ANKRD26P4.
- chr13:75,109,587–75,109,693, 1 gene: RNU6-38P.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
